Somatic mutation profile of tumor specimen CDDP-ABM9-TTP1-A (aliquot CDDP-ABM9-TTP1-A-1-0-D-A500-36) from CDDP_EAGLE case CDDP-ABM9, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 52 years.
Specimen CDDP-ABM9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5214f7fd-0e85-4061-be3d-bed1696ea70d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ABM9-NC1-A (Buccal Cell Normal), aliquot CDDP-ABM9-NC1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5df1548e-7edc-4345-be30-84e96320b6c6

The open-access MAF lists 396 somatic variants for this specimen: 274 protein-altering or splice-affecting, 80 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 237, Silent 80, Intron 21, Nonsense Mutation 14, Splice Site 10, Frame Shift Del 7, 5'Flank 6, RNA 5, 5'UTR 4, Splice Region 3, 3'UTR 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.13321C>T p.Q4441* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as rs1261703349, COSV60953975; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 46/233 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- UBE3A | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs587780584, CM1412897, COSV51664621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61005674; called by muse, varscan2
- ADAM7 | c.2032C>G p.L678V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV51539351, COSV51544357; called by muse, mutect2, varscan2
- ADAMTS2 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 66/291 reads (23%) | catalogued as COSV51077048; called by muse, mutect2, varscan2
- ADAMTS2 | c.582G>T p.L194F | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV51077144; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2708G>T p.R903I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54446363; called by muse, varscan2
- ADAT2 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV52794234; called by muse, mutect2, varscan2
- ADGRB3 | c.2281G>T p.V761F | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV65393510; called by muse, varscan2
- AHNAK2 | c.11999C>T p.A4000V | Missense Mutation (SNP) | VAF 34/367 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as rs1216152832; called by muse, mutect2
- AKAP13 | c.4274A>T p.E1425V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.69); catalogued as COSV63455936; called by muse, varscan2
- ALPI | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs900759974, COSV55014491; called by muse, mutect2, varscan2
- ALPK2 | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV64492708; called by muse, mutect2, varscan2
- ANK1 | c.3788A>T p.D1263V | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs1293516474, COSV55880464; called by muse, mutect2, varscan2
- ANK2 | c.2673G>T p.L891F | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV52159182; called by muse, mutect2, varscan2
- ARHGEF11 | c.838G>T p.D280Y | Missense Mutation (SNP) | VAF 62/423 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100810115, COSV63812113; called by muse, mutect2, varscan2
- ASTN1 | c.2925C>A p.N975K | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV62496306; called by muse, varscan2
- ATF6 | c.1240C>G p.Q414E | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV63407321; called by muse, mutect2
- ATP2B3 | c.3377A>G p.Y1126C | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1557022275, COSV54845964; called by muse, mutect2
- BNC2 | c.1285A>C p.M429L | Missense Mutation (SNP) | VAF 123/311 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV66146303; called by muse, mutect2, varscan2
- BNC2 | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 177/472 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV66146312; called by muse, mutect2, varscan2
- BSN | c.7460G>T p.G2487V | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as COSV56517156; called by muse, mutect2, varscan2
- C10orf88 | c.747A>T p.L249F | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV64403911; called by muse, mutect2, varscan2
- CACNA1S | c.3167T>A p.M1056K | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62939109; called by muse, mutect2, varscan2
- CCDC141 | c.3476G>C p.G1159A | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV55372915; called by muse, mutect2, varscan2
- CCDC141 | c.839C>A p.S280* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV69459127; called by muse, mutect2
- CCDC181 | c.559T>C p.S187P | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63156333; called by muse, mutect2, varscan2
- CCN5 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV51937038; called by muse, mutect2, varscan2
- CCSER1 | c.2324C>A p.T775K | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.075); catalogued as COSV61427653; called by muse, mutect2, varscan2
- CD101 | c.2737G>T p.E913* | Nonsense Mutation (SNP) | VAF 31/124 reads (25%) | catalogued as COSV56717782; called by muse, mutect2, varscan2
- CD3G | c.314A>T p.Q105L | Missense Mutation (SNP) | VAF 75/370 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV52674747; called by muse, mutect2, varscan2
- CEACAM4 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV55731527; called by muse, mutect2
- CLEC16A | c.3014A>G p.E1005G | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV55489641; called by muse, mutect2
- COL11A1 | c.4840C>A p.H1614N | Missense Mutation (SNP) | VAF 82/395 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV62182412, COSV62199468; called by muse, mutect2, varscan2
- COL4A4 | c.202G>T p.G68* | Nonsense Mutation (SNP) | VAF 22/161 reads (14%) | catalogued as COSV61631796; called by muse, mutect2, varscan2
- COL9A3 | c.1854G>T p.Q618H | Missense Mutation (SNP) | VAF 159/558 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV58984757; called by muse, mutect2, varscan2
- COX18 | c.824C>G p.P275R | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55719680, COSV99887000; called by muse, mutect2
- CPA3 | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV56044955, COSV56047565; called by muse, mutect2, varscan2
- CR1L | c.521G>T p.R174I | Missense Mutation (SNP) | VAF 64/384 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54325536; called by muse, mutect2
- CR1L | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 64/390 reads (16%) | catalogued as COSV54325556, COSV54328937; called by muse, mutect2
- CRNKL1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55628009; called by muse, mutect2, varscan2
- CTNNA2 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs376745664; called by mutect2, varscan2
- CTNNA3 | c.820G>T p.G274* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV65578044; called by muse, mutect2
- CTNND2 | c.2235C>A p.Y745* | Nonsense Mutation (SNP) | VAF 48/188 reads (26%) | catalogued as COSV100475089, COSV58885948; called by muse, mutect2, varscan2
- CUBN | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV64714879; called by muse, mutect2
- DCTN3 | c.21G>T p.L7F | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV52407162; called by muse, mutect2, varscan2
- DCUN1D1 | c.413A>C p.K138T | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53044393; called by muse, mutect2, varscan2
- DDX3X | c.1023-1G>A p.X341_splice (on ENST00000399959; = p.X342_splice on NM_001356.5) | Splice Site (SNP) | VAF 40/86 reads (47%) | catalogued as COSV67863966; called by muse, mutect2, varscan2
- DDX3Y | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 101/171 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.273); catalogued as COSV60176869; called by muse, varscan2
- DENND5B | c.2539A>G p.I847V | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs1478175275, COSV60902324; called by muse, mutect2, varscan2
- DGKI | c.955G>T p.V319F | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV55948313; called by muse, mutect2, varscan2
- DNAAF3 | c.1493A>T p.Q498L (on ENST00000524407 / NM_001256715.2; = p.Q545L on NM_178837.4) | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.094); catalogued as rs536068494, COSV61276108; called by muse, mutect2, varscan2
- DSC3 | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64572802; called by mutect2, varscan2
- DSC3 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 61/376 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64572811; called by muse, mutect2, varscan2
- DUOXA1 | c.310G>T p.G104W | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146078577, COSV50993446; called by muse, mutect2, varscan2
- ENPP7 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1263330435, COSV60386372; called by muse, mutect2
- ERICH6B | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.042); catalogued as COSV53919815; called by muse, mutect2, varscan2
- F5 | c.4301G>A p.S1434N | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs745549085, COSV63123569; called by muse, mutect2
- FAM47A | c.1782C>G p.C594W | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV60495513, COSV60496322; called by muse, mutect2, varscan2
- FAM83D | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 157/530 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54157330; called by muse, mutect2, varscan2
- FAT3 | c.8969T>A p.L2990Q | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53105708; called by muse, mutect2, varscan2
- FBXO32 | c.335C>A p.A112D | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54890903, COSV54891143; called by muse, mutect2, varscan2
- FBXW9 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.219); catalogued as COSV63508240; called by muse, mutect2, varscan2
- FCGR2B | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 90/861 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.929); catalogued as COSV52681397; called by muse, varscan2
- FDXR | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.115); catalogued as rs541381194, COSV53121695, COSV53125229; called by muse, mutect2, varscan2
- FGA | c.2570G>T p.R857L | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs376940583, COSV57394202; called by muse, mutect2, varscan2
- FYB1 | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 99/353 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV60945659; called by muse, mutect2, varscan2
- GCC1 | c.2222A>G p.Q741R | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV58462452; called by muse, mutect2, varscan2
- GCC2 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV59175987; called by muse, mutect2, varscan2
- GDA | c.1240G>T p.G414W | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV52992597; called by muse, mutect2, varscan2
- GGCX | c.2012G>C p.R671P | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV52088160, COSV52089335; called by muse, mutect2, varscan2
- GHSR | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 153/742 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53838822; called by muse, mutect2, varscan2
- GPR176 | c.1089A>G p.I363M | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54444850; called by muse, mutect2, varscan2
- GPSM1 | c.1183G>T p.D395Y | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV61303924; called by muse, mutect2, varscan2
- GRIA2 | c.1704C>A p.S568R | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52389099; called by muse, mutect2, varscan2
- GRIN2A | c.1595G>A p.G532E | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV58031099; called by muse, mutect2, varscan2
- GRIN2A | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100411129; called by muse, mutect2
- H2BC15 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 31/335 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); catalogued as COSV57585574; called by muse, mutect2
- HDAC7 | c.2009A>G p.H670R (on ENST00000427332; = p.H709R on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50346331; called by muse, mutect2
- HGF | c.74C>A p.A25D | Missense Mutation (SNP) | VAF 183/363 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.149); catalogued as COSV55948803; called by muse, mutect2, varscan2
- HGFAC | c.1528T>A p.C510S | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66976842; called by muse, mutect2, varscan2
- HK1 | c.2397G>T p.Q799H | Missense Mutation (SNP) | VAF 37/310 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53856470, COSV53857387; called by muse, mutect2, varscan2
- HRH3 | c.177C>G p.F59L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781490425, COSV58048457; called by muse, mutect2, varscan2
- IGF2R | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63628718; called by muse, mutect2, varscan2
- IGHV2-5 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs1065554; called by muse, mutect2, varscan2
- IL17RA | c.608G>T p.W203L | Missense Mutation (SNP) | VAF 107/673 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60052970; called by muse, mutect2, varscan2
- IPO9 | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV64233576; called by muse, mutect2, varscan2
- ITGB8 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.74); catalogued as rs761695849, COSV56007894; called by muse, mutect2, varscan2
- ITPRID1 | c.2329C>A p.Q777K | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.085); catalogued as COSV60073895; called by muse, mutect2, varscan2
- JUP | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs782455234, COSV60277325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNH3 | c.1946T>C p.L649P | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV57790633; called by muse, mutect2, varscan2
- KCTD18 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as rs931785255, COSV63344286; called by muse, mutect2, varscan2
- KRT28 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV60685025; called by muse, mutect2, varscan2
- LCN12 | c.199A>T p.T67S | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.56); catalogued as COSV65421725; called by muse, mutect2, varscan2
- LCT | c.4676G>T p.R1559M | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV51547135, COSV51548517; called by muse, mutect2
- LRRC71 | c.1104G>T p.M368I | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61656188, COSV61656478; called by muse, mutect2, varscan2
- LRRK2 | c.5554A>G p.I1852V | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs147442556; called by muse, mutect2, varscan2
- LRRTM1 | c.513C>A p.N171K | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54444317, COSV99702818; called by muse, mutect2, varscan2
- LRRTM4 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV69139945, COSV69140059; called by muse, varscan2
- LTBP1 | c.2782C>A p.Q928K (on ENST00000404816 / NM_206943.4; = p.Q602K on NM_000627.4) | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as rs763248715, COSV63185956, COSV63187321; called by muse, mutect2, varscan2
- MAEL | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63304957; called by muse, mutect2, varscan2
- MAGEA12 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1556833530; called by muse, mutect2, varscan2
- MAN2A1 | c.2549G>T p.R850L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV54851163; called by muse, mutect2, varscan2
- MAP4K1 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV67710171; called by muse, mutect2, varscan2
- MIA3 | c.69G>T p.Q23H | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV60512358; called by muse, mutect2, varscan2
- MISP | c.1936G>T p.G646C | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.685); catalogued as COSV53119890; called by muse, mutect2, varscan2
- MME | c.257A>T p.Y86F | Missense Mutation (SNP) | VAF 77/352 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.641); catalogued as COSV64707201; called by muse, mutect2, varscan2
- MMP20 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 106/551 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV52775329; called by muse, mutect2, varscan2
- MMP3 | c.589T>A p.F197I | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55405940; called by muse, mutect2, varscan2
- MORC2 | c.1471A>G p.M491V (on ENST00000397641 / NM_001303256.3; = p.M429V on NM_014941.3) | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs767798376, COSV53198331; called by muse, mutect2, varscan2
- MPPED1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.465); catalogued as rs749571377, COSV61987482; called by muse, mutect2, varscan2
- MROH6 | c.1558C>T p.L520F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.646); catalogued as COSV67338657; called by muse, mutect2, varscan2
- MUC5B | c.2735G>T p.S912I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV71591885; called by muse, mutect2, varscan2
- MYH15 | c.1532A>T p.E511V | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56309219; called by muse, mutect2, varscan2
- MYO10 | c.1303A>G p.I435V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72563035; called by muse, mutect2, varscan2
- MYPN | c.234G>T p.L78F | Missense Mutation (SNP) | VAF 62/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62733596; called by muse, varscan2
- MYPN | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62733603; called by muse, varscan2
- MYT1L | c.2637-1G>A p.X879_splice | Splice Site (SNP) | VAF 8/40 reads (20%) | catalogued as COSV67728191; called by muse, mutect2, varscan2
- NCKAP1L | c.2485G>A p.E829K | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs778805911, COSV53206360; called by muse, mutect2
- NFATC2 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV65353772; called by muse, mutect2, varscan2
- NGF | c.357C>A p.S119R | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV65687609; called by muse, mutect2, varscan2
- NOD2 | c.2307G>C p.L769F | Missense Mutation (SNP) | VAF 103/838 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1266638330, COSV56050431; called by muse, mutect2, varscan2
- NPAP1 | c.3211C>A p.Q1071K | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as rs1306045762, COSV61506575; called by muse, mutect2, varscan2
- NPTXR | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100285619, COSV60728276; called by muse, mutect2, varscan2
- NR1H4 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 36/179 reads (20%) | catalogued as COSV58094484; called by muse, mutect2, varscan2
- NR3C2 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV60989828; called by muse, mutect2, varscan2
- NRG3 | c.2066C>G p.T689R (on ENST00000404547 / NM_001370084.1; = p.T665R on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100932452, COSV64559422, COSV64586615; called by muse, mutect2
- NRXN3 | c.1323G>C p.E441D (on ENST00000335750 / NM_001330195.2; = p.E68D on NM_004796.6) | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV100201247, COSV59743907; called by muse, mutect2
- NUDT7 | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV51745257; called by muse, mutect2, varscan2
- NUP214 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs777405728, COSV63909301; called by muse, mutect2, varscan2
- OR2L8 | c.548T>C p.M183T | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV61726656; called by muse, mutect2, varscan2
- OR2M2 | c.169A>T p.T57S | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV62898257; called by muse, mutect2, varscan2
- OR2T2 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 75/612 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1427854490, COSV61618745; called by muse, mutect2, varscan2
- OR4A5 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs768038244, COSV60522381; called by muse, mutect2
- OR4K2 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs765250674, COSV53849298; called by muse, mutect2, varscan2
- OR52N1 | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 77/269 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV57693297; called by muse, mutect2, varscan2
- OR9Q1 | c.727C>A p.H243N | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59039859; called by muse, mutect2, varscan2
- P2RY8 | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs747936708, COSV67178092; called by mutect2, varscan2
- PAK5 | c.991-1G>T p.X331_splice | Splice Site (SNP) | VAF 16/86 reads (19%) | catalogued as COSV62038727; called by muse, varscan2
- PALLD | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 50/200 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54979792; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.53C>A p.S18Y (on ENST00000259318 / NM_001136562.3; = p.S249Y on NM_007203.5) | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV52175798; called by muse, mutect2, varscan2
- PARP16 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as rs1468612461, COSV56035242; called by muse, mutect2, varscan2
- PCDHGB1 | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV53939773; called by muse, mutect2, varscan2
- PCLO | c.14006G>T p.G4669V | Missense Mutation (SNP) | VAF 136/252 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV61620896, COSV61632791; called by muse, mutect2, varscan2
- PCNX3 | c.3749C>T p.A1250V | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63136575; called by muse, mutect2
- PDZD3 | c.601G>T p.A201S (on ENST00000531114; = p.A135S on NM_024791.4) | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV52704079; called by muse, mutect2, varscan2
- PGAP4 | c.1019C>A p.P340Q | Missense Mutation (SNP) | VAF 84/312 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV66387603; called by muse, mutect2, varscan2
- PHLPP1 | c.2804G>T p.R935L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53027869, COSV53028042; called by muse, mutect2, varscan2
- PKP1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 181/532 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs764623008, COSV104380576; called by muse, mutect2, varscan2
- PLCH1 | c.136G>C p.E46Q (on ENST00000340059 / NM_001130960.2; = p.E58Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100395946, COSV58195843; called by muse, mutect2, varscan2
- PLXNA3 | c.2741G>T p.C914F | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63753992; called by muse, mutect2, varscan2
- POTEE | c.2690G>T p.G897V | Missense Mutation (SNP) | VAF 69/1232 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV58229939; called by muse, mutect2
- POU2F1 | c.39G>C p.E13D (on ENST00000541643 / NM_001365848.1; = p.E36D on NM_002697.4) | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.132); catalogued as COSV54816538, COSV54824775; called by muse, mutect2, varscan2
- PPARGC1A | c.1002T>A p.S334R | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as COSV53527186, COSV99339032; called by muse, mutect2, varscan2
- PPP1R9A | c.3080T>G p.L1027R | Missense Mutation (SNP) | VAF 76/140 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56891365; called by muse, varscan2
- PRAG1 | c.3943C>T p.R1315C | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1448304987, COSV58160454; called by muse, mutect2, varscan2
- PRDM9 | c.2383C>A p.Q795K | Missense Mutation (SNP) | VAF 102/844 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV57005843; called by muse, varscan2
- PRR35 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.277); catalogued as COSV53462712; called by muse, mutect2, varscan2
- PRUNE2 | c.7216C>T p.Q2406* | Nonsense Mutation (SNP) | VAF 22/194 reads (11%) | catalogued as COSV65041119; called by muse, mutect2, varscan2
- PTPRD | c.3925G>C p.E1309Q | Missense Mutation (SNP) | VAF 127/253 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61937735, COSV61943159; called by muse, mutect2, varscan2
- PTPRD | c.2326G>T p.E776* | Nonsense Mutation (SNP) | VAF 31/62 reads (50%) | catalogued as COSV61931835; called by muse, mutect2, varscan2
- RAD54B | c.1527G>T p.K509N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); catalogued as COSV60251020; called by muse, varscan2
- RAMP3 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs370868982; called by muse, mutect2
- RASAL1 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV55655691; called by muse, mutect2, varscan2
- RBM10 | c.2351A>T p.H784L | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61308125; called by muse, mutect2, varscan2
- RBM20 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.167); catalogued as COSV65703958; called by muse, mutect2, varscan2
- RIMS2 | c.1394C>A p.A465D (on ENST00000666250 / NM_001348490.2; = p.A273D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51677893; called by muse, mutect2, varscan2
- RINL | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV50875078; called by muse, mutect2, varscan2
- RNF103 | c.1598A>T p.Q533L | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV52894673; called by muse, mutect2, varscan2
- RNF113B | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760628427, COSV57434952; called by muse, mutect2, varscan2
- RP1L1 | c.3218G>T p.R1073L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.163); catalogued as COSV66753696, COSV66754580; called by muse, mutect2, varscan2
- RPTOR | c.967A>T p.I323F | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60808060; called by muse, mutect2
- RTL1 | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.184); catalogued as COSV66016761; called by muse, mutect2, varscan2
- RYR1 | c.2365C>G p.R789G | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62096035, COSV62096223; called by muse, mutect2, varscan2
- RYR2 | c.7591T>A p.C2531S | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.959); catalogued as COSV63683207; called by muse, mutect2
- RYR2 | c.12176C>A p.T4059K | Missense Mutation (SNP) | VAF 71/454 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV63683218, COSV63698482; called by muse, mutect2, varscan2
- SCG2 | c.1494C>G p.N498K | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100544628, COSV59539843; called by muse, mutect2, varscan2
- SCLT1 | c.1406G>T p.R469I | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV55405283; called by muse, mutect2, varscan2
- SCN1A | c.4867G>T p.E1623* (on ENST00000303395 / NM_001202435.3; = p.E1612* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 159/414 reads (38%) | catalogued as rs1553520516, COSV57668913, COSV99066795; called by muse, mutect2, varscan2
- SDCCAG8 | c.675G>T p.L225= | Splice Region (SNP) | VAF 80/496 reads (16%) | catalogued as COSV59408626; called by muse, mutect2, varscan2
- SDK2 | c.1616G>T p.G539V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV66185430; called by muse, mutect2
- SETDB2 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749907751, COSV51644343; called by muse, mutect2, varscan2
- SEZ6L | c.1595G>A p.G532D | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50663025; called by muse, mutect2, varscan2
- SLC20A1 | c.319G>T p.V107F | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55611158; called by muse, mutect2, varscan2
- SLC35E3 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV60117858; called by muse, mutect2, varscan2
- SLC39A12 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.427); catalogued as COSV66197780; called by muse, mutect2
- SLC9A7 | c.606A>T p.R202S | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60379826; called by muse, mutect2, varscan2
- SLITRK1 | c.1576C>A p.L526I | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65675367; called by muse, mutect2, varscan2
- SMYD1 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1314099546, COSV70225029; called by muse, mutect2, varscan2
- SORCS3 | c.2587G>C p.D863H | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100863345; called by muse, mutect2
- SPEN | c.6550G>C p.A2184P | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65361295, COSV65363016; called by muse, mutect2, varscan2
- SPTBN4 | c.6643G>C p.A2215P | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV58948655; called by muse, mutect2, varscan2
- SSTR1 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); catalogued as COSV57455803; called by muse, mutect2, varscan2
- STK33 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs936275480, COSV59397545; called by muse, mutect2, varscan2
- SVEP1 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57035287; called by muse, mutect2, varscan2
- TAS2R3 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 82/150 reads (55%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV56091938, COSV56092295; called by muse, mutect2, varscan2
- TCHH | c.4250G>T p.R1417L | Missense Mutation (SNP) | VAF 85/574 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.787); catalogued as rs370960477, COSV64274616; called by muse, mutect2, varscan2
- TG | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55074537; called by muse, mutect2, varscan2
- TLR4 | c.289G>T p.A97S (on ENST00000355622 / NM_138554.5; = p.A57S on NM_003266.4) | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.345); catalogued as COSV62922362, COSV62923174; called by muse, mutect2, varscan2
- TMEM132C | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV59420864, COSV59437633; called by muse, mutect2, varscan2
- TMPRSS9 | c.652T>A p.S218T (on ENST00000648592; = p.S184T on NM_182973.2) | Missense Mutation (SNP) | VAF 71/289 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60227301; called by muse, mutect2, varscan2
- TOPAZ1 | c.691T>A p.C231S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV59067268; called by muse, mutect2, varscan2
- TP53 | c.703A>G p.N235D | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as CM941331, COSV52678348, COSV52809353, COSV52980321, COSV53037756; called by muse, mutect2, varscan2
- TPP2 | c.839C>G p.P280R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV101060354, COSV65752419; called by muse, mutect2, varscan2
- TRIM58 | c.421G>T p.V141L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV63570070; called by muse, mutect2, varscan2
- TRIM60 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.842); catalogued as COSV61970418; called by muse, mutect2, varscan2
- TRPM5 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 22/341 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as rs781438299; called by muse, mutect2
- TTC3 | c.5706G>T p.K1902N | Missense Mutation (SNP) | VAF 91/229 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV61289809; called by muse, mutect2, varscan2
- TUBA3C | c.296C>A p.A99E | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV67139194, COSV67139325; called by muse, mutect2, varscan2
- UBE3A | c.1867A>G p.I623V | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51664607; called by muse, mutect2, varscan2
- URB2 | c.2443G>A p.V815I | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs368807322; called by muse, mutect2, varscan2
- USP31 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV54851840; called by muse, mutect2, varscan2
- VWC2 | c.540C>A p.C180* | Nonsense Mutation (SNP) | VAF 62/191 reads (32%) | catalogued as COSV61484707; called by muse, mutect2, varscan2
- XKR7 | c.699G>T p.L233F | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73813168; called by muse, mutect2, varscan2
- ZNF101 | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV58908869; called by muse, mutect2, varscan2
- ZNF142 | c.4750C>T p.L1584F (on ENST00000411696 / NM_001379660.1; = p.L1384F on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV68743618; called by muse, mutect2, varscan2
- ZNF207 | c.924T>G p.N308K | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.848); catalogued as COSV58299780; called by muse, mutect2, varscan2
- ZNF235 | c.124A>T p.R42W | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV52156298; called by muse, mutect2, varscan2
- ZNF268 | c.2120G>T p.S707I | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV57212805; called by muse, mutect2, varscan2
- ZPLD1 | c.677G>T p.G226V (on ENST00000466937 / NM_001329788.1; = p.G242V on NM_175056.2) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.582); catalogued as COSV60353322; called by muse, mutect2, varscan2
- ZSCAN1 | c.782A>T p.H261L | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV56604046; called by muse, mutect2, varscan2
- ABCF1 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ACSM2A | c.493C>A p.Q165K (on ENST00000219054; = p.Q86K on NM_001308169.2) | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAMTS10 | c.1661_1664del p.T554Nfs*82 | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- ADAMTS20 | c.5713C>A p.L1905I | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.2258-2A>C p.X753_splice | Splice Site (SNP) | VAF 12/66 reads (18%) | called by muse, varscan2
- ALKBH7 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- AMBRA1 | c.2802G>A p.M934I (on ENST00000458649 / NM_001367468.1; = p.M844I on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2
- ANKRD45 | c.731-1G>T p.X244_splice | Splice Site (SNP) | VAF 11/169 reads (7%) | called by muse, mutect2
- CBWD5 | c.56G>T p.C19F | Missense Mutation (SNP) | VAF 43/406 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- COL22A1 | c.3610G>T p.G1204W | Missense Mutation (SNP) | VAF 11/276 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- COL7A1 | c.7983+1G>T p.X2661_splice | Splice Site (SNP) | VAF 40/229 reads (17%) | called by muse, mutect2, varscan2
- COL7A1 | c.1901del p.G634Afs*56 | Frame Shift Del (DEL) | VAF 145/521 reads (28%) | called by mutect2, pindel, varscan2
- CTNNA2 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.797); called by muse, mutect2
- DENND4B | c.640+8G>T | Splice Region (SNP) | VAF 42/291 reads (14%) | called by muse, mutect2, varscan2
- DNAJC22 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- EFHB | c.1177+1_1177+5delinsAAAAA p.X393_splice | Splice Site (ONP) | VAF 6/41 reads (15%) | called by pindel, varscan2*
- EXOC7 | c.1866-7C>T | Splice Region (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- FAM24A | c.50G>T p.S17I | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FSD1L | c.1224del p.K409Nfs*43 | Frame Shift Del (DEL) | VAF 109/546 reads (20%) | called by mutect2, pindel, varscan2
- HIBADH | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HYDIN | c.2375dup p.L792Ffs*62 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- KIF23 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LCE1F | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEF2D | c.778del p.Q260Sfs*22 | Frame Shift Del (DEL) | VAF 37/276 reads (13%) | called by mutect2, pindel, varscan2
- MNAT1 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC19 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MUC5B | c.8279C>A p.S2760Y | Missense Mutation (SNP) | VAF 56/336 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NAT8L | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NETO2 | c.353T>C p.I118T | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NYX | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR11H2 | c.775C>A p.L259I (on ENST00000556246; = p.L270I on NM_001197287.1) | Missense Mutation (SNP) | VAF 54/535 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.04); called by mutect2, varscan2
- OR2M7 | c.618G>T p.M206I | Missense Mutation (SNP) | VAF 80/477 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- OS9 | c.1712A>T p.Q571L | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- P2RY12 | c.690del p.R231Gfs*4 | Frame Shift Del (DEL) | VAF 39/217 reads (18%) | called by mutect2, pindel, varscan2
- PARP4 | c.3369G>T p.M1123I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PPP2R5B | c.372dup p.V125Rfs*21 | Frame Shift Ins (INS) | VAF 30/175 reads (17%) | called by mutect2, pindel
- PRSS57 | c.712T>C p.W238R | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RBP3 | c.2276C>A p.A759D | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RYR2 | c.9068-2A>T p.X3023_splice | Splice Site (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- SERINC4 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 81/341 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- SLC18B1 | c.125_133del p.S42_N44del | In Frame Del (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel, varscan2
- SNTG2 | c.757A>T p.S253C | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SPIC | c.650T>C p.V217A | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- SRFBP1 | c.198+2T>C p.X66_splice | Splice Site (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- TADA1 | c.495C>G p.D165E | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.205); called by muse, mutect2
- TCF19 | c.712A>G p.S238G | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- WBP11 | c.1184A>T p.Q395L | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR27 | c.587del p.P196Rfs*2 | Frame Shift Del (DEL) | VAF 34/158 reads (22%) | called by mutect2, pindel, varscan2
- WDR7 | c.967-5_970delinsTTTTTTTTT p.X323_splice | Splice Site (ONP) | VAF 6/74 reads (8%) | called by mutect2*, pindel
- WDR76 | c.86del p.N29Tfs*7 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel
- ZAN | c.307C>G p.R103G | Missense Mutation (SNP) | VAF 120/241 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- ZNF726 | c.1053C>G p.S351R | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.053); called by muse, mutect2
- ABCC11 | c.609G>T p.V203= | Silent (SNP) | VAF 89/290 reads (31%) | catalogued as COSV62322867, COSV62326182; called by muse, mutect2, varscan2
- ADAM7 | c.2031C>A p.V677= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV51539339; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4176T>C p.S1392= | Silent (SNP) | VAF 41/129 reads (32%) | catalogued as COSV54446382; called by muse, mutect2, varscan2
- AICDA | c.171G>A p.V57= | Silent (SNP) | VAF 28/283 reads (10%) | catalogued as COSV57564273; called by muse, mutect2, varscan2
- ANO5 | c.273G>A p.K91= | Silent (SNP) | VAF 28/275 reads (10%) | catalogued as COSV61084572; called by muse, mutect2, varscan2
- ATP2B2 | c.792G>T p.V264= | Silent (SNP) | VAF 51/317 reads (16%) | catalogued as COSV59495572; called by muse, mutect2, varscan2
- AUTS2 | c.135G>T p.A45= | Silent (SNP) | VAF 102/193 reads (53%) | catalogued as COSV61398975; called by muse, mutect2, varscan2
- BAG6 | c.744A>T p.P248= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- BDH1 | c.223C>T p.L75= | Silent (SNP) | VAF 38/226 reads (17%) | catalogued as rs1452909046, COSV64018436; called by muse, mutect2, varscan2
- CD163 | c.535C>A p.R179= | Silent (SNP) | VAF 44/143 reads (31%) | catalogued as COSV63131936, COSV63133746; called by muse, mutect2, varscan2
- CDH26 | c.756A>G p.E252= | Silent (SNP) | VAF 8/242 reads (3%) | catalogued as COSV54846475; called by muse, mutect2
- CEP120 | c.996G>T p.V332= | Silent (SNP) | VAF 23/156 reads (15%) | catalogued as COSV60265362; called by muse, mutect2, varscan2
- COL25A1 | c.1851C>T p.F617= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV67649778; called by muse, mutect2, varscan2
- CSNK1D | c.549C>T p.N183= | Silent (SNP) | VAF 36/317 reads (11%) | catalogued as COSV53924254; called by muse, mutect2, varscan2
- CYB561D1 | c.42G>A p.G14= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV60204705; called by muse, mutect2, varscan2
- DIAPH2 | c.3129C>T p.L1043= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV61268550; called by muse, mutect2, varscan2
- DNAJB11 | c.333G>T p.G111= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV54002545; called by muse, mutect2, varscan2
- ENPP7 | c.594G>T p.P198= | Silent (SNP) | VAF 65/213 reads (31%) | catalogued as COSV60386358; called by muse, mutect2, varscan2
- FBXL7 | c.246G>A p.G82= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV61645418; called by muse, mutect2, varscan2
- FGB | c.324A>T p.T108= | Silent (SNP) | VAF 46/242 reads (19%) | catalogued as COSV57418190; called by muse, mutect2, varscan2
- FGB | c.861C>T p.D287= | Silent (SNP) | VAF 35/247 reads (14%) | catalogued as rs146831181, COSV57418196; called by muse, mutect2, varscan2
- FHOD3 | c.3753A>G p.L1251= (on ENST00000359247 / NM_001281739.3; = p.L1268= on NM_025135.5) | Silent (SNP) | VAF 37/198 reads (19%) | catalogued as COSV57172341; called by muse, mutect2, varscan2
- GABRG1 | c.588C>A p.P196= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV54953489; called by muse, mutect2, varscan2
- GALNT17 | c.300G>A p.P100= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as rs770531592, COSV61167193; called by muse, mutect2, varscan2
- GRIK3 | c.1032C>A p.T344= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV66139224; called by muse, mutect2, varscan2
- GRIP1 | c.1650G>T p.T550= (on ENST00000359742 / NM_001379345.1; = p.T498= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 57/282 reads (20%) | catalogued as rs1369161246, COSV54022542, COSV54038894; called by muse, mutect2, varscan2
- GUCY2F | c.1848G>T p.S616= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV54300391, COSV54301405; called by muse, mutect2, varscan2
- INPP5J | c.375C>T p.P125= | Silent (SNP) | VAF 63/263 reads (24%) | called by muse, mutect2, varscan2
- ITPRID1 | c.2328C>A p.P776= | Silent (SNP) | VAF 58/275 reads (21%) | catalogued as COSV60073880; called by muse, mutect2, varscan2
- KAT6A | c.304C>T p.L102= | Silent (SNP) | VAF 18/454 reads (4%) | catalogued as rs1164383666, COSV55905696; called by muse, mutect2
- KRAS | c.33T>C p.A11= | Silent (SNP) | VAF 46/229 reads (20%) | catalogued as rs397517039, COSV55688436; ClinVar: likely benign; called by muse, mutect2, varscan2
- LDLRAD3 | c.804T>A p.P268= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as COSV59682158; called by muse, varscan2
- LGR6 | c.399G>T p.A133= (on ENST00000367278 / NM_001017403.1; = p.A81= on NM_021636.3) | Silent (SNP) | VAF 25/197 reads (13%) | catalogued as rs767577005, COSV55156394; called by muse, mutect2, varscan2
- MAP4 | c.3201C>G p.A1067= | Silent (SNP) | VAF 32/209 reads (15%) | catalogued as COSV53137262; called by muse, mutect2, varscan2
- MIA3 | c.3267G>T p.V1089= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as COSV60512365; called by muse, mutect2, varscan2
- MINK1 | c.2187C>G p.P729= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- MROH6 | c.1557G>T p.G519= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs1361285921, COSV67338663; called by muse, mutect2, varscan2
- MTG2 | c.786C>T p.H262= | Silent (SNP) | VAF 67/205 reads (33%) | catalogued as rs138973644, COSV63693764; called by muse, mutect2, varscan2
- MYO3B | c.705C>T p.P235= | Silent (SNP) | VAF 61/171 reads (36%) | catalogued as COSV58702187; called by muse, mutect2, varscan2
- NCAPD2 | c.2784C>T p.S928= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV59699203; called by muse, mutect2, varscan2
- NEK11 | c.1605G>T p.L535= | Silent (SNP) | VAF 45/214 reads (21%) | catalogued as COSV67281199; called by muse, mutect2, varscan2
- NR5A1 | c.615A>T p.P205= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV65294863; called by muse, mutect2
- OR2H1 | c.360A>G p.R120= | Silent (SNP) | VAF 51/161 reads (32%) | called by muse, mutect2, varscan2
- OR4Q3 | c.720G>A p.Q240= | Silent (SNP) | VAF 16/244 reads (7%) | catalogued as COSV59177621, COSV59178508; called by muse, mutect2
- OR52B2 | c.834G>A p.L278= | Silent (SNP) | VAF 32/362 reads (9%) | catalogued as COSV73209335; called by muse, mutect2
- OR52N5 | c.849C>T p.H283= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV57698814; called by muse, mutect2, varscan2
- OR6Y1 | c.870C>A p.L290= | Silent (SNP) | VAF 30/237 reads (13%) | catalogued as COSV56929299; called by muse, mutect2, varscan2
- PAK5 | c.108C>A p.P36= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as COSV62026625, COSV62038640; called by muse, mutect2, varscan2
- PCDH15 | c.1914A>T p.L638= | Silent (SNP) | VAF 97/361 reads (27%) | catalogued as rs908121801, COSV57303431; called by muse, mutect2, varscan2
- PCDHA4 | c.1272G>A p.V424= | Silent (SNP) | VAF 68/321 reads (21%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.1965G>T p.T655= | Silent (SNP) | VAF 74/249 reads (30%) | catalogued as COSV53939796; called by muse, mutect2, varscan2
- PIK3R5 | c.1386C>A p.P462= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV52653417; called by muse, mutect2, varscan2
- PTPRF | c.1278C>T p.S426= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as rs556161672, COSV63442617; called by muse, mutect2, varscan2
- RALYL | c.48C>A p.P16= | Silent (SNP) | VAF 41/244 reads (17%) | catalogued as COSV72820309; called by muse, mutect2, varscan2
- RBBP6 | c.408G>A p.S136= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs559784053, COSV60504867; called by muse, mutect2
- RBM20 | c.111C>A p.G37= | Silent (SNP) | VAF 23/179 reads (13%) | called by muse, mutect2, varscan2
- SLC35G4 | c.594G>T p.L198= | Silent (SNP) | VAF 34/337 reads (10%) | called by muse, mutect2
- SLC5A5 | c.489C>T p.D163= | Silent (SNP) | VAF 70/459 reads (15%) | catalogued as rs1005011923, COSV55832802; called by muse, mutect2, varscan2
- SORBS1 | c.2346T>C p.N782= (on ENST00000361941 / NM_001034954.2; = p.N529= on NM_024991.3 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 17/166 reads (10%) | catalogued as COSV53357024; called by muse, mutect2, varscan2
- SPTBN4 | c.435C>T p.I145= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV100150148, COSV58948616; called by muse, mutect2
- SPTSSB | c.174C>A p.R58= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as COSV63219168; called by muse, mutect2, varscan2
- SRGAP2 | c.2955G>T p.V985= (on ENST00000624873 / NM_001170637.4; = p.V986= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/223 reads (20%) | called by muse, mutect2, varscan2
- STARD9 | c.10887T>A p.P3629= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV51903571; called by muse, mutect2, varscan2
- STRA6 | c.1971G>T p.T657= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV51433660; called by muse, mutect2, varscan2
- TAS1R2 | c.312C>A p.I104= | Silent (SNP) | VAF 33/278 reads (12%) | catalogued as rs200799920, COSV64744762; called by muse, mutect2, varscan2
- TBC1D9 | c.1071G>A p.V357= | Silent (SNP) | VAF 32/125 reads (26%) | called by muse, mutect2, varscan2
- TBCCD1 | c.1098A>T p.V366= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV58662073; called by muse, mutect2, varscan2
- TCN1 | c.132C>A p.I44= | Silent (SNP) | VAF 49/269 reads (18%) | catalogued as COSV57253020, COSV57253091; called by muse, mutect2, varscan2
- THBS1 | c.1149T>C p.S383= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV52951692; called by muse, mutect2, varscan2
- THG1L | c.510G>A p.K170= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as COSV51452321; called by muse, mutect2
- TLR5 | c.855G>T p.L285= | Silent (SNP) | VAF 64/507 reads (13%) | catalogued as COSV60558853; called by muse, mutect2, varscan2
- TMC1 | c.1921C>T p.L641= | Silent (SNP) | VAF 55/531 reads (10%) | catalogued as rs1318364193, COSV52774527; called by muse, mutect2
- TOX2 | c.36G>C p.A12= | Silent (SNP) | VAF 61/331 reads (18%) | catalogued as COSV57885847, COSV57897430, COSV57898102; called by muse, mutect2, varscan2
- TRIM15 | c.177C>A p.L59= | Silent (SNP) | VAF 94/243 reads (39%) | called by muse, mutect2, varscan2
- TRIM64B | c.174C>A p.T58= | Silent (SNP) | VAF 199/1231 reads (16%) | called by muse, mutect2, varscan2
- TRPM6 | c.4887G>T p.V1629= | Silent (SNP) | VAF 38/334 reads (11%) | called by muse, mutect2, varscan2
- UROC1 | c.993G>T p.T331= | Silent (SNP) | VAF 61/344 reads (18%) | catalogued as COSV52033415; called by muse, mutect2, varscan2
- VOPP1 | c.264G>T p.P88= | Silent (SNP) | VAF 12/105 reads (11%) | catalogued as COSV53384672, COSV53386781; called by muse, mutect2, varscan2
- WDR87 | c.3717C>T p.G1239= | Silent (SNP) | VAF 49/217 reads (23%) | catalogued as rs1053213618, COSV58198025; called by muse, mutect2, varscan2
- ZNF765 | c.1509C>T p.F503= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV67182483; called by muse, mutect2, varscan2
- AC107023.1 | chr12:40446596 G>T | 5'Flank (SNP) | VAF 23/90 reads (26%) | catalogued as rs555086665; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83389G>T | Intron (SNP) | VAF 38/347 reads (11%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.1472+60G>T | Intron (SNP) | VAF 7/35 reads (20%) | catalogued as COSV56410340, COSV99856600; called by muse, mutect2, varscan2
- ALG9 | chr11:111786125 T>C | 3'Flank (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- APP | c.1687+8748A>G | Intron (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- ARID3A | c.-13G>A | 5'UTR (SNP) | VAF 18/149 reads (12%) | catalogued as rs1031618901; called by muse, mutect2, varscan2
- C11orf21 | c.54-151G>T | Intron (SNP) | VAF 26/137 reads (19%) | catalogued as COSV51719741; called by muse, mutect2, varscan2
- CASP8 | c.1-8122C>T | Intron (SNP) | VAF 37/480 reads (8%) | called by muse, mutect2
- CEP41 | c.*4866C>T | 3'UTR (SNP) | VAF 38/378 reads (10%) | catalogued as rs782719539; ClinVar: uncertain significance; called by muse, mutect2
- CNTN2 | c.392-14G>A | Intron (SNP) | VAF 32/204 reads (16%) | called by muse, mutect2, varscan2
- DCHS2 | n.7829G>A | RNA (SNP) | VAF 18/162 reads (11%) | catalogued as COSV61769612; called by muse, mutect2, varscan2
- EOLA1 | chrX:149549424 G>C | 3'Flank (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- EPS8L3 | c.1563+22C>A | Intron (SNP) | VAF 26/130 reads (20%) | called by muse, mutect2, varscan2
- FAM182B | n.612C>A | RNA (SNP) | VAF 138/667 reads (21%) | called by mutect2, varscan2
- FUBP3 | c.*7G>T | 3'UTR (SNP) | VAF 24/238 reads (10%) | called by muse, mutect2
- FUT7 | chr9:137034689 C>A | 5'Flank (SNP) | VAF 48/201 reads (24%) | called by muse, mutect2, varscan2
- GCSAML | c.-56-10385C>A | Intron (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- HS1BP3 | c.920+1595G>A | Intron (SNP) | VAF 29/155 reads (19%) | catalogued as rs1422205925; called by muse, mutect2, varscan2
- IFNA6 | c.-2C>A | 5'UTR (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1172-27714_1172-27711del | Intron (DEL) | VAF 14/133 reads (11%) | called by mutect2, pindel
- LILRB2 | c.1360+77C>A | Intron (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- LINC02656 | n.315C>A | RNA (SNP) | VAF 38/147 reads (26%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+710del | Intron (DEL) | VAF 28/160 reads (18%) | catalogued as rs1344749776; called by mutect2, pindel, varscan2
- MATK | chr19:3789284 G>C | 5'Flank (SNP) | VAF 13/130 reads (10%) | catalogued as COSV59554415, COSV59556154; called by muse, mutect2, varscan2
- MLLT10 | c.240+12902_240+12907delinsTTTTAA | Intron (ONP) | VAF 5/42 reads (12%) | called by muse*, pindel
- MMP26 | c.-145+92430T>A | Intron (SNP) | VAF 13/223 reads (6%) | called by muse, mutect2
- NICN1 | c.495+60A>T | Intron (SNP) | VAF 60/277 reads (22%) | called by muse, mutect2, varscan2
- NOX4 | c.1516-37C>A | Intron (SNP) | VAF 6/28 reads (21%) | called by muse, varscan2
- OR11H2 | chr14:19713912 C>A | 5'Flank (SNP) | VAF 32/275 reads (12%) | catalogued as rs867680297; called by muse, mutect2, varscan2
- OR2W5 | n.1136C>T | RNA (SNP) | VAF 38/356 reads (11%) | called by muse, mutect2
- PCMTD1 | c.-387G>T | 5'UTR (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2
- PDE5A | c.-82G>T | 5'UTR (SNP) | VAF 11/144 reads (8%) | called by muse, mutect2
- PDZRN3 | c.919-3790C>A | Intron (SNP) | VAF 28/134 reads (21%) | called by muse, mutect2, varscan2
- PLCB1 | c.2524-6206C>T | Intron (SNP) | VAF 40/133 reads (30%) | catalogued as rs750234080; called by muse, mutect2, varscan2
- PRR16 | c.159+16529G>T | Intron (SNP) | VAF 10/55 reads (18%) | called by muse, varscan2
- RN7SL106P | chr15:23163842 C>G | 5'Flank (SNP) | VAF 95/837 reads (11%) | called by muse, mutect2, varscan2
- SLC4A11 | chr20:3239090 C>A | 5'Flank (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- STAU2 | c.1530+24295A>G | Intron (SNP) | VAF 24/184 reads (13%) | catalogued as COSV72922127; called by muse, mutect2, varscan2
- TMEM44 | c.612+21G>T | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as rs753799795; called by muse, mutect2, varscan2
- TMPRSS11BNL | n.299G>T | RNA (SNP) | VAF 11/115 reads (10%) | called by muse, mutect2
- TRAC | chr14:22557078 A>T | 3'Flank (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- ZNF99 | c.*178G>T | 3'UTR (SNP) | VAF 31/189 reads (16%) | called by muse, mutect2, varscan2
